Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A162, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A162-01A (Primary Tumor).

[page 1 of 2]
ICB-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Surgical Pathology Site Code: Endometrium C54.1

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 B1 B2 B3 B4 B5 B6 B7 B8
B9 B10 B11
B12 B13 B14 C1 C2 C3 C4 C5 C6 C7 C8 C9 C10 D1 E1 F1 F2 F3
G1 H1

Uterus, right ovary (2.1 x 2.0 x 0.6 cm) with 8.1 cm
segment of
right fallopian tube, and left ovary (2.0 x 1.0 x 0.8 cm)
with 7.2
cm segment of left fallopian tube together weighing 145.0
grams,
separately submitted right and left pelvic lymph nodes,
right and
left para-aortic lymph nodes and left gonadal vessel
(overall
specimen, 10.3 x 3.0 x 0.5 cm, 8.3 cm in length).

DIAGNOSIS:

Uterus, endometrium/myometrium, hysterectomy: Endometrial
adenocarcinoma, endometrioid type, FIGO grade I (of III),
forming a
polypoid mass (4.1 x 3.6 x 1.4 cm). The tumor invades
into the
myometrium at a depth of 1.0 cm (myometrium thickness 1.9
cm).

Uterus, cervix, hysterectomy: No diagnostic abnormality.

Ovaries and fallopian tubes, right and left salpingo-
oophorectomies:

No diagnostic abnormality.

Lymph nodes, right pelvic, excision: Multiple (10
external iliac, 1
internal iliac, 3 common and 8 obturator) right pelvic
lymph nodes
are negative for tumor.

Lymph nodes, left pelvic, excision: Multiple (6 external
iliac, 3
internal iliac, 4 obturator and 10 common iliac) left
pelvic lymph
nodes are negative for tumor.

[page 2 of 2]
Lymph nodes, right para-aortic, excision: Multiple (1
above and 1
below the inferior mesenteric artery) right para-aortic
lymph nodes
are negative for tumor.

Lymph nodes, left para-aortic, excision: Multiple (11
above and 3
below the inferior mesenteric artery) left para-aortic
lymph nodes
are negative for tumor.

Gonadal vessel, left, excision: No diagnostic
abnormalities,
negative for tumor.

IPVA Discrepancy		☒

Source: NCI Genomic Data Commons file 14b0983a-3266-44f3-bf77-8ded671623eb (TCGA-D1-A162.CB5E7FA1-33EE-492F-B2B0-F4C9332640A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).